Gene-level copy-number profile of tumor specimen TCGA-CH-5753-01A from TCGA case TCGA-CH-5753, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.6 years (25,780 days).
Specimen TCGA-CH-5753-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ebf1e8f2-5a63-4dc2-9469-11d3ba3fd19e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5753-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e59acc8a-904e-4d0a-886e-e3febd4c4e78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 10,811; copy number 2: 46,518; copy number 3: 2,879; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5753-01A-11D-1574-01): tumor purity 0.83, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:26,771,790–26,772,140, 1 gene: AC091675.1.
- chr8:28,767,661–28,890,242, 1 gene (within-gene range 0–1): INTS9.
- chr8:28,810,103–29,064,764, 6 genes: AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2.
- chr8:29,067,279–29,068,454, 1 gene: AC108449.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,628,899, 5 genes, copy number 5: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.

Autosomal genes at a single copy (total copy number 1): 8,433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
